Somatic mutation profile of tumor specimen TARGET-30-PALZSL-01A (aliquot TARGET-30-PALZSL-01A-01W) from TARGET case TARGET-30-PALZSL, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 4.3 years (1,564 days).
Specimen TARGET-30-PALZSL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae5cba6a-dd8c-42eb-bf21-71487ed16176.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PALZSL-10A (Blood Derived Normal), aliquot TARGET-30-PALZSL-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/358b1adc-9941-4bc2-bd5c-b2acc340fcc3

The open-access MAF lists 37 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 9, Splice Region 1, Nonsense Mutation 1, RNA 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGDIB | c.416C>A p.A139E | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.006); catalogued as COSV56764615; called by muse, mutect2, varscan2
- DLGAP4 | c.1790G>T p.S597I | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59422527; called by muse, mutect2, varscan2
- KRTAP4-4 | c.230A>G p.Q77R | Missense Mutation (SNP) | VAF 62/364 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1314507131; called by muse, mutect2, varscan2
- OR2D2 | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 14/170 reads (8%) | catalogued as COSV55056460, COSV55057158; called by muse, mutect2
- OR51M1 | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 218/498 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); catalogued as COSV60785299; called by muse, mutect2
- OR7E24 | c.523C>A p.Q175K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV71702339; called by muse, mutect2, varscan2
- OR8B8 | c.84C>A p.F28L | Missense Mutation (SNP) | VAF 28/473 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.101); catalogued as COSV60143662; called by muse, mutect2
- PGAM4 | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58452445; called by muse, mutect2, varscan2
- PGLYRP3 | c.1012C>A p.H338N | Missense Mutation (SNP) | VAF 135/829 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.578); catalogued as COSV51950132, COSV51951620; called by muse, mutect2, varscan2
- PSMD3 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 150/286 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs1356688688; called by muse, varscan2
- RNF25 | c.643G>T p.A215S | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.514); catalogued as COSV55309285; called by muse, mutect2, varscan2
- RNF31 | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.52); PolyPhen benign (0.253); catalogued as COSV60728313; called by muse, mutect2, varscan2
- SIGLEC6 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 89/139 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV58437008; called by muse, mutect2, varscan2
- TBC1D32 | c.3549C>A p.F1183L | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV51543568; called by muse, mutect2
- UFC1 | c.436C>A p.L146M | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as COSV57090892; called by muse, mutect2, varscan2
- ZNF222 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV51828139; called by muse, mutect2, varscan2
- ZNF569 | c.2015G>T p.S672I | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV57598498; called by muse, mutect2, varscan2
- CDHR4 | c.404-3C>A | Splice Region (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2
- DCC | c.1930C>A p.L644M | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2
- H1-6 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2
- IGHG2 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 142/782 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- IPO11 | c.2837A>G p.E946G | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- ITGAM | c.2476G>T p.D826Y (on ENST00000648685 / NM_001145808.2; = p.D825Y on NM_000632.4) | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2
- KRTAP4-4 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 63/363 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MPP7 | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XRCC6 | c.961-1G>T p.X321_splice | Splice Site (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- CXCL13 | c.78C>A p.V26= | Silent (SNP) | VAF 62/425 reads (15%) | catalogued as COSV54493234; called by muse, mutect2, varscan2
- FLG | c.2028C>T p.S676= | Silent (SNP) | VAF 333/749 reads (44%) | catalogued as COSV64247414; called by muse, mutect2, varscan2
- HRNR | c.2883C>A p.G961= | Silent (SNP) | VAF 30/354 reads (8%) | catalogued as rs1373178990, COSV100912993; called by muse, mutect2
- RPS6KB1 | c.1251T>A p.S417= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- SIGLEC5 | c.801G>T p.L267= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV55783010; called by muse, mutect2, varscan2
- SLC22A3 | c.582C>T p.V194= | Silent (SNP) | VAF 30/346 reads (9%) | called by muse, mutect2
- SLC2A3 | c.885C>A p.I295= | Silent (SNP) | VAF 24/276 reads (9%) | called by muse, mutect2
- TMEM40 | c.156C>A p.S52= | Silent (SNP) | VAF 10/362 reads (3%) | catalogued as COSV53148198; called by muse, mutect2
- UGT8 | c.81G>T p.P27= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV60420387, COSV60420811; called by muse, mutect2, varscan2
- MIR519E | n.25G>A | RNA (SNP) | VAF 22/154 reads (14%) | catalogued as rs1199021002; called by muse, varscan2
- SH3KBP1 | c.520+607C>T | Intron (SNP) | VAF 28/28 reads (100%) | catalogued as rs771715244; called by muse, mutect2, varscan2
